CCDI case PBCNSJ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Bones, joints and articular cartilage of limbs.
https://portal.gdc.cancer.gov/cases/d4ad4539-ed1b-4025-b574-8b9fb2fce194

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Synovial sarcoma, NOS: ICD-O-3 morphology code: 9040/3; Tissue or organ of origin: Upper limb, NOS; Age at diagnosis: 13.9 years (5,093 days).

Biospecimens (1 sample)
- Sample 0DW6C7: Tissue type: Tumor; Specimen type: Solid Tissue.
